MMRF case MMRF_1736 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/26cbfdd2-a32d-43ae-b97b-26abc9896c59

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.2 years (28,913 days); ISS stage: II; Days to last known disease status: 1,146 days (3.1 years); Days to last follow up: 1,146 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 34 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -30 (ECOG 0): M Protein 5.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 54.3 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.3 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 10.2 g/dL; Glucose 6.38 mmol/L.
- Day 68: M Protein 0.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 8.43 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.8 µg/mL.
- Day 121: M Protein 0.33 g/dL; Immunoglobulin G 7.23 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 1.27 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.13 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 6.55 mmol/L.
- Day 250: M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.548 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.771 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.92 g/L; Beta 2 Microglobulin 2.52 µg/mL.
- Day 300: M Protein 0.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.663 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.588 mg/dL; Immunoglobulin G 9.65 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 1.82 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.27 ×10⁹/L; Platelets 330 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 6.6 mmol/L.
- Day 411: M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.807 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.75 g/L; Beta 2 Microglobulin 2.84 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.56 ×10⁹/L; Platelets 522 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 10.1 mmol/L.
- Day 502: M Protein 0.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.652 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 8 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 618: M Protein 1.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.681 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 2.51 µg/mL.
- Day 714: M Protein 1.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.994 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.85 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 6.38 mmol/L.
- Day 813: M Protein 1.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.86 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 3.73 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 7.21 mmol/L.
- Day 896: M Protein 1.43 g/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.56 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.94 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 8.69 mmol/L.
- Day 980: M Protein 1.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.895 mg/dL; Immunoglobulin G 19.2 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.1 g/dL; Glucose 9.08 mmol/L.
- Day 1,023: M Protein 1.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.724 mg/dL; Immunoglobulin G 22.6 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.49 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.71 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 7.8 g/dL; Glucose 7.59 mmol/L.
- Day 1,146: M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 35.6 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 8.5 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day -30: Weight: 75 kg; Height: 168 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Multiple Myeloma.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample MMRF_1736_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -30 days.
- Sample MMRF_1736_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -30 days.
